Somatic mutation profile of tumor specimen TARGET-10-PANVIC-03A (aliquot TARGET-10-PANVIC-03A-01D) from TARGET case TARGET-10-PANVIC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,766 days).
Specimen TARGET-10-PANVIC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa50755e-45f1-4394-8a7c-b3031b6984f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVIC-14A (Bone Marrow Normal), aliquot TARGET-10-PANVIC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acfd2427-967b-4f60-a15f-cdd77af07190

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIC4 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61731254; called by muse, mutect2, varscan2
- DDR2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs747307320, COSV100906553, COSV63373949; called by muse, mutect2, varscan2
- MCHR1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs1330901475, COSV50760335; called by muse, mutect2, varscan2
- TTC3 | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.138); catalogued as COSV61289813; called by mutect2, varscan2
- TTC3 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV61292312; called by muse, mutect2, varscan2
- VPS18 | c.816C>G p.F272L | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.134); catalogued as COSV99592804; called by muse, mutect2, varscan2
- FLT3 | c.2428A>G p.R810G | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NANOS2 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NRM | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPAP1 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH2B3 | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AZGP1 | c.613+207G>T | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as rs999055822; called by muse, varscan2
- HDAC7 | c.2675-184_2675-177delinsAAA | Intron (DEL) | VAF 24/35 reads (69%) | called by pindel, varscan2*
- SNRPG | c.*31C>T | 3'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as rs763564874; called by muse, varscan2
